Somatic mutation profile of tumor specimen BA2669D (aliquot aq-BA2669D) from BEATAML1.0 case 2155, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Primary diagnosis: Acute promyelocytic leukaemia, PML-RAR-alpha; Tissue or organ of origin: Bone marrow; Age at diagnosis: 24.1 years (8,814 days).
Specimen BA2669D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be3edbc8-9791-4b16-bc4d-b2d9dffd3602.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2120D (Solid Tissue Normal), aliquot aq-BA2120D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ae9036a-e8c7-4068-8a16-60256b1e992c

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP17A1 | c.928G>T p.V310L | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as COSV64005045; called by muse, mutect2
- RPS6KA4 | c.1540G>A p.V514M | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53701738, COSV53701770; called by muse, mutect2, varscan2
- NXF3 | c.806A>G p.K269R | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.609); called by muse, mutect2
- FAIM2 | c.63G>T p.V21= | Silent (SNP) | VAF 5/52 reads (10%) | called by muse, mutect2
- RORB | c.402C>T p.S134= (on ENST00000396204 / NM_001365023.1; = p.S123= on NM_006914.4) | Silent (SNP) | VAF 49/111 reads (44%) | called by muse, mutect2, varscan2
